Gene-level copy-number profile of tumor specimen TCGA-BR-8486-01A from TCGA case TCGA-BR-8486, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-BR-8486-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.b7014736-8e5f-475b-a248-9ea231489a1a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-8486-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/14401a0d-f0f8-43aa-a3fa-0fa904b58e8e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 20,334; copy number 2: 34,483; copy number 3: 4,330; copy number 4: 202; copy number 5: 195; copy number 6: 69; copy number 7: 91; copy number 10: 99.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-8486-01A-31D-2390-01): tumor purity 0.65, ploidy 1.75, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:43,472,477–43,485,880, 2 genes: Y_RNA, AC097638.1.
- chr10:50,264,978–50,625,163, 5 genes (within-gene range 0–1): DYNC1I2P1, SGMS1, AC069547.2, AC069547.1, AL117341.1.
- chr10:50,705,380–50,885,675, 6 genes: CTSLP4, PGGT1BP1, AL589794.2, ASAH2B, A1CF, AL512366.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 454 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:39,553,811–40,000,527, 8 genes, copy number 6 (within-gene range 1–6): E2F4P1, RNU1-54P, DAAM2, AL592158.1, DAAM2-AS1, MOCS1, TUBBP9, FO393411.1.
- chr6:41,101,022–44,830,188, 143 genes, copy number 6–10 (within-gene range 1–10) (broad region; genes not listed).
- chr12:51,328,442–51,812,864, 6 genes, copy number 7 (within-gene range 2–7): CELA1, GALNT6, SLC4A8, AC107031.1, SCN8A, HNRNPA3P10.
- chr20:43,063,326–45,491,671, 85 genes, copy number 7 (broad region; genes not listed).
- chr20:57,648,392–64,313,132, 212 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 20,334. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
